Somatic mutation profile of tumor specimen C3L-00183-03 (aliquot CPT0066470010) from CPTAC case C3L-00183, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 33.8 years (12,359 days).
Specimen C3L-00183-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fdb6281-3159-4f22-84ae-f628cfcd305f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00183-31 (Blood Derived Normal), aliquot CPT0070990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fdaa228-78dc-419f-8814-7e236cd5803b

The open-access MAF lists 50 somatic variants for this specimen: 39 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 6, Frame Shift Del 4, In Frame Del 3, Intron 3, 5'UTR 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.1987G>T p.G663C | Missense Mutation (SNP) | VAF 53/356 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72653780, CM073963, COSV52741710; ClinVar: pathogenic; called by mutect2, varscan2
- ADAM33 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs776750383, COSV100598191; called by muse, mutect2, varscan2
- BAZ2B | c.3842T>C p.L1281S | Missense Mutation (SNP) | VAF 86/398 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.841); catalogued as rs1214430411; called by muse, varscan2
- CBLL2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100081385; called by muse, mutect2, varscan2
- GGCX | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 105/488 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as rs1297397846; called by muse, mutect2, varscan2
- IDO2 | c.302C>T p.A101V (on ENST00000389060; = p.A114V on NM_194294.2) | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs1249765602, COSV100584888; called by muse, mutect2, varscan2
- KLB | c.2948C>G p.T983R | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs749646287; called by muse, mutect2, varscan2
- MAP3K21 | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs747180331, COSV64041075; called by muse, mutect2, varscan2
- MYO3A | c.2635+1G>A p.X879_splice | Splice Site (SNP) | VAF 50/335 reads (15%) | catalogued as rs762313427; called by muse, mutect2, varscan2
- SLC23A3 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs763989453; called by muse, mutect2, varscan2
- STK31 | c.2578G>C p.V860L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV63460849; called by muse, mutect2, varscan2
- TRMU | c.675del p.K226Rfs*22 | Frame Shift Del (DEL) | VAF 167/857 reads (19%) | catalogued as COSV51989918; called by mutect2, pindel, varscan2
- ZSWIM8 | c.3218G>A p.G1073E (on ENST00000605216 / NM_001242487.2; = p.G1078E on NM_015037.3) | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1287014697, COSV55218313; called by muse, mutect2, varscan2
- AADAT | c.161_174del p.T54Kfs*38 | Frame Shift Del (DEL) | VAF 28/173 reads (16%) | called by mutect2, pindel
- ABCA2 | c.5753C>G p.T1918R (on ENST00000614293; = p.T1888R on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTSL2 | c.697A>T p.T233S | Missense Mutation (SNP) | VAF 117/708 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BICD2 | c.340T>A p.Y114N | Missense Mutation (SNP) | VAF 87/391 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- C19orf57 | c.994T>A p.S332T | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CALD1 | c.2256A>T p.K752N (on ENST00000361675 / NM_033138.4; = p.K497N on NM_004342.7) | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCNO | c.503C>A p.T168K | Missense Mutation (SNP) | VAF 58/425 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CKAP2L | c.1652_1654del p.A551del | In Frame Del (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- DMXL2 | c.3984T>G p.I1328M | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- GPATCH2 | c.589A>G p.R197G | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPA8 | c.1033A>G p.K345E | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- KRT3 | c.691A>T p.N231Y | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- LAMC2 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAN2A2 | c.2766C>A p.F922L | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- OMA1 | c.470_475del p.V157_K159delinsE | In Frame Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- PSG6 | c.1011_1020del p.Y337* | Frame Shift Del (DEL) | VAF 44/206 reads (21%) | called by mutect2, pindel
- RNASEK-C17orf49 | c.6T>G p.D2E | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPGRIP1L | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SBF1 | c.4571C>A p.P1524H | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC14L1 | c.1898_1903del p.I633_Q635delinsK | In Frame Del (DEL) | VAF 21/90 reads (23%) | called by mutect2, pindel, varscan2
- SLC22A24 | c.462del p.S156Hfs*6 | Frame Shift Del (DEL) | VAF 39/192 reads (20%) | called by mutect2, pindel, varscan2
- TMEM184B | c.481T>G p.W161G | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM192 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- TMIGD2 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM41 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- ZHX2 | c.1657T>C p.F553L | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- CHST1 | c.895T>C p.L299= | Silent (SNP) | VAF 47/263 reads (18%) | called by muse, mutect2, varscan2
- CSK | c.780C>T p.G260= | Silent (SNP) | VAF 42/259 reads (16%) | catalogued as rs930375989; called by muse, mutect2, varscan2
- DCHS1 | c.139C>T p.L47= | Silent (SNP) | VAF 53/328 reads (16%) | called by muse, mutect2, varscan2
- DNAJB14 | c.633T>G p.P211= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- ITGAE | c.1135C>T p.L379= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as COSV53994825; called by muse, mutect2, varscan2
- KIAA1109 | c.2970T>C p.Y990= | Silent (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- COMT | c.615+18T>C | Intron (SNP) | VAF 94/446 reads (21%) | called by muse, mutect2, varscan2
- EZH2 | c.247-4239G>A | Intron (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2
- FANCA | c.2222+42G>T | Intron (SNP) | VAF 47/211 reads (22%) | called by muse, mutect2, varscan2
- KRTAP19-2 | c.*1G>C | 3'UTR (SNP) | VAF 32/200 reads (16%) | called by muse, mutect2
- SLC6A9 | c.-34G>T | 5'UTR (SNP) | VAF 35/187 reads (19%) | called by muse, mutect2, varscan2
